Somatic mutation profile of tumor specimen TCGA-J9-A8CP-01A (aliquot TCGA-J9-A8CP-01A-11D-A34U-08) from TCGA case TCGA-J9-A8CP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,299 days).
Specimen TCGA-J9-A8CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5beff891-c850-4016-9bc6-3bf718334bf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A8CP-10A (Blood Derived Normal), aliquot TCGA-J9-A8CP-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c553dbc-44b8-47f3-b0a9-d844103fa9d8

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, RNA 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4066C>A p.P1356T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV101166064; called by muse, mutect2, varscan2
- ADGRL1 | c.2690A>G p.K897R (on ENST00000340736 / NM_001008701.3; = p.K892R on NM_014921.5) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100529248; called by muse, mutect2, varscan2
- ANKRD55 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100591031, COSV100591488; called by muse, mutect2
- CDH10 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100049983; called by muse, mutect2, varscan2
- CHD4 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.164); catalogued as rs1358073566, COSV100537292; called by muse, mutect2, varscan2
- DNAH7 | c.6566G>T p.G2189V | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413782; called by muse, mutect2
- DNAI1 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1325002464, COSV99646550; called by muse, mutect2, varscan2
- ERICH6 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs112279628, COSV99901328; called by muse, varscan2
- KCNK18 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 9/175 reads (5%) | catalogued as COSV100571970; called by muse, mutect2
- MED13 | c.2693A>G p.D898G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101180747; called by muse, mutect2, varscan2
- MYH10 | c.5678C>T p.A1893V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as rs778680463, COSV52610943; called by muse, mutect2, varscan2
- NBAS | c.5701T>G p.F1901V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99867014; called by muse, mutect2, varscan2
- NIPBL | c.1321A>C p.T441P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV99238672; called by muse, mutect2, varscan2
- PDZD8 | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100559390; called by muse, mutect2, varscan2
- POLR1A | c.1114C>G p.R372G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs752860605, COSV99807082; called by muse, mutect2
- POU5F2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs575553090, COSV101232649; called by muse, mutect2, varscan2
- PPP1R3A | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144397367, COSV52887227; called by muse, mutect2, varscan2
- THOC5 | c.967-2A>G p.X323_splice | Splice Site (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100803444; called by muse, mutect2, varscan2
- TMEM94 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756526309, COSV58594318; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835788; called by muse, mutect2, varscan2
- USP8 | c.1912A>G p.R638G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100208722; called by muse, mutect2, varscan2
- CDH10 | c.1920dup p.E641Rfs*18 | Frame Shift Ins (INS) | VAF 16/117 reads (14%) | called by mutect2, varscan2
- FOXA1 | c.781_787del p.R262Sfs*57 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- CLOCK | c.2343A>C p.P781= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100011576; called by muse, mutect2, varscan2
- ITCH | c.1998T>A p.R666= (on ENST00000262650 / NM_001257137.3; = p.R625= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV99391952; called by muse, mutect2, varscan2
- PLXNB2 | c.3174G>C p.P1058= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1341853236, COSV100833847, COSV100834012; called by muse, mutect2, varscan2
- PPOX | c.1005G>A p.V335= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99237116; called by muse, mutect2, varscan2
- SUPV3L1 | c.132C>T p.V44= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV100669492; called by muse, mutect2, varscan2
- DCHS2 | n.4365C>A | RNA (SNP) | VAF 49/149 reads (33%) | catalogued as COSV100601042, COSV61778627; called by muse, mutect2, varscan2
- UBE2D2 | c.24+517G>A | Intron (SNP) | VAF 3/24 reads (13%) | catalogued as rs1224154176, COSV99551284, COSV99551491; called by muse, mutect2
